CPTAC case C3L-01744 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1272f46b-0d75-496b-8f06-cb659d9e22a7

Demographics
Sex at birth: female; Race: white; Year of birth: 1954; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Age at diagnosis: 62.4 years (22,808 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,381 days (3.8 years); Progression or recurrence: no; Days to last follow up: 1,381 days (3.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.2 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (5 entries)
- Days to follow up: 392 days (1.1 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 781 days (2.1 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 953 days (2.6 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 953 days (2.6 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,381 days (3.8 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.

Other clinical attributes
- Weight: 104.33 kg; Height: 149.86 cm; BMI: 46.45.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01744-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 17 days; Initial weight: 220 mg; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01744-21: Section location: Anterior endometrium; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-01744-02: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 70 mg.
- Sample C3L-01744-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 17 days; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Samples C3L-01744-31, C3L-01744-32 (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Sample C3L-01744-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 17 days; Method of sample procurement: Blood Draw.
